Somatic mutation profile of tumor specimen MP2PRT-PAVNLM-TBP1-A (aliquot MP2PRT-PAVNLM-TBP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVNLM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,967 days).
Specimen MP2PRT-PAVNLM-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdfc125d-5d6a-49cc-be3d-66709a109e1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVNLM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVNLM-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7323273e-d5e6-46f2-9476-6a71476f264f

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Del 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 35/430 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 43/328 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 37/324 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- AKAP6 | c.4960G>A p.V1654I | Missense Mutation (SNP) | VAF 131/427 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as rs138495771; called by muse, mutect2, varscan2
- COLEC11 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 131/338 reads (39%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.84); catalogued as rs754115098, COSV52598860; called by muse, mutect2, varscan2
- CREB3L1 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 124/551 reads (23%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs368441030; called by muse, mutect2, varscan2
- FLNC | c.3371C>T p.T1124M | Missense Mutation (SNP) | VAF 56/392 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375013141, COSV57958626; called by muse, mutect2, varscan2
- INPPL1 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 172/560 reads (31%) | catalogued as COSV53358580, COSV99996625; called by muse, mutect2, varscan2
- PLEKHG3 | c.2590G>A p.E864K (on ENST00000394691; = p.E920K on NM_001308147.2) | Missense Mutation (SNP) | VAF 156/616 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as rs765262218; called by muse, mutect2, varscan2
- RBMXL2 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 163/594 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV60978701; called by muse, mutect2, varscan2
- SMARCA4 | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 189/657 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs778175819, COSV60785488, COSV60786996; called by muse, mutect2, varscan2
- STON2 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 122/404 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.078); catalogued as rs745574107; called by muse, varscan2
- TAB1 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 148/508 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.026); catalogued as rs762013018; called by muse, mutect2, varscan2
- NEIL3 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 115/418 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- SHANK2 | c.157_176delinsTTCGGACAG p.Q53Ffs*9 | Frame Shift Del (DEL) | VAF 98/501 reads (20%) | called by pindel, varscan2*
- DACT2 | c.156G>A p.P52= | Silent (SNP) | VAF 133/506 reads (26%) | called by muse, mutect2, varscan2
- GRM4 | c.759G>A p.S253= | Silent (SNP) | VAF 35/314 reads (11%) | catalogued as rs1416728164, COSV65214063; called by muse, mutect2, varscan2
- LSR | c.297C>T p.H99= | Silent (SNP) | VAF 42/427 reads (10%) | called by muse, mutect2
- LTBP1 | c.3171A>G p.E1057= (on ENST00000404816 / NM_206943.4; = p.E731= on NM_000627.4) | Silent (SNP) | VAF 124/288 reads (43%) | called by muse, mutect2, varscan2
- MTNR1A | c.471G>A p.A157= | Silent (SNP) | VAF 42/530 reads (8%) | catalogued as rs374634426; called by muse, mutect2
- NAV3 | c.2024-12736A>G | Intron (SNP) | VAF 116/426 reads (27%) | called by muse, mutect2, varscan2
